Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4475, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4475-01A (Primary Tumor).

■

Diagnosis:

- 1.: Gastric stump resection material with a poorly differentiated ulcerous and mucinous adenocarcinoma in the region of anastomosis, predominantly of the intestinal type, but very focally of the diffuse type, with infiltration of the perigastric fatty tissue, a carcinomatous lymphangitis of the subserosa, tumor-free resection margins in the region of the mucosa, a tumor-free omentum and two lymph node metastases (15 lymph nodes examined).
- 2.: Tumor-free lymph node tissue (5 lymph nodes examined).

Tumor classification: mucinous adenocarcinoma (diffuse type) ■ pT3 N1 (2/20) L1 V0 R0

Source: NCI Genomic Data Commons file c2563cde-9ca5-4a6c-aa08-2206ed0ef4b7 (TCGA-CG-4475.5F6DC898-0D32-4721-BD04-745083D0357C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).